Gene-level copy-number profile of specimen HCM-CSHL-0366-C50-85B from HCMI case HCM-CSHL-0366-C50, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Metaplastic carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 46.9 years (17,140 days).
Specimen HCM-CSHL-0366-C50-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8a3c6bb9-9b31-4baf-aa72-13dbbd19e23e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0366-C50-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/f2517c91-9886-489c-8917-faf07a0aa6db

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 27; copy number 1: 2,422; copy number 2: 31,187; copy number 3: 14,775; copy number 4: 6,696; copy number 5: 1,474; copy number 6: 1,327; copy number 7: 335; copy number 8: 90; copy number 9: 54; copy number 10: 7.

Homozygous deletions (total copy number 0; autosomes only): 27 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:75,384,059–75,590,649, 11 genes: AC139453.2, LSP1P2, AC139453.1, ALG1L6P, FAM86DP, LINC02018, ENPP7P2, SNRPCP10, AC133041.1, RPS3AP15, AC108724.1.
- chr9:21,802,636–22,128,103, 14 genes (within-gene range 0–2): MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr11:55,648,327–55,652,854, 1 gene: OR4S2.
- chr11:55,673,536–55,674,675, 1 gene: OR4V1P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,276 genes in 40 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 1 gene, copy number 5 (within-gene range 2–5): RSRP1.
- chr1:25,266,102–25,337,465, 4 genes, copy number 5: AL031432.2, RHD, SDHDP6, AL928711.1.
- chr1:40,863,914–46,516,216, 191 genes, copy number 6–7 (broad region; genes not listed).
- chr1:54,715,861–55,064,852, 13 genes, copy number 6 (within-gene range 4–6): TTC4, PARS2, TTC22, AC096536.1, LEXM, DHCR24, AC096536.3, AC096536.2, DHCR24-DT, TMEM61, AL590440.1, BSND, PCSK9.
- chr1:58,933,643–59,240,555, 1 gene, copy number 6 (within-gene range 3–6): LINC01358.
- chr1:59,131,932–62,178,675, 26 genes, copy number 5–6: HSD52, AC093424.1, FGGY, MIR4711, AL035416.1, HOOK1, CYP2J2, RN7SL475P, C1orf87, PGBD4P8, LINC02778, LINC01748, AC099792.1, NFIA, NFIA-AS2, NFIA-AS1, AC099791.1, TM2D1, AC099791.2, PATJ, RNU6-414P, RNU6-1177P, LAMTOR5P1, RN7SL180P, MIR3116-1, MIR3116-2.
- chr1:62,688,482–62,710,694, 1 gene, copy number 7: AC103923.1.
- chr1:63,593,411–66,801,256, 43 genes, copy number 5–7 (within-gene range 3–7): PGM1, RN7SL130P, ROR1, AL161742.1, CFL1P3, RNU6-809P, Y_RNA, ROR1-AS1, UBE2U, RNU7-62P, CACHD1, MIR4794, RAVER2, JAK1, AL606517.2, AL606517.1, LINC01359, SLC2A3P2, AL357078.2, RNU6-1176P, MIR3671, MIR101-1, AL357078.1, MRPS21P1, AK4, RPS29P7, DNAJC6, AL139294.1, COX6CP13, RNU2-15P, LEPROT, LEPR, AC119800.1, AC097063.1, RN7SL854P, PDE4B, PDE4B-AS1, RNU4-88P, SGIP1, MIR3117, AL139147.1, TCTEX1D1, INSL5.
- chr1:67,522,299–67,833,467, 8 genes, copy number 6 (within-gene range 3–6): LINC01702, RNU6-1031P, AL590559.1, RN7SL392P, HNRNPCP9, GADD45A, GNG12, RNU7-80P.
- chr1:69,433,255–70,531,492, 18 genes, copy number 5: LINC01758, LRRC7, SGO1P1, AL117353.1, RN7SL538P, PIN1P1, LRRC7-AS1, LRRC40, RN7SL242P, SRSF11, AL353771.1, ANKRD13C, HHLA3, HHLA3-AS1, CTH, Metazoa_SRP, AL354872.1, CHORDC1P5.
- chr1:143,419,625–145,739,288, 76 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr1:159,171,609–163,076,802, 165 genes, copy number 5 (broad region; genes not listed).
- chr1:173,141,100–248,937,043, 1,462 genes, copy number 5–8 (broad region; genes not listed).
- chr3:11,745–409,417, 7 genes, copy number 6: LINC01986, AC066595.1, CHL1-AS2, CHL1, RNU6-1194P, RPS8P6, CHL1-AS1.
- chr3:78,597,239–79,958,142, 6 genes, copy number 6: ROBO1, AC055731.1, RN7SL751P, AC117461.1, MIR3923, HMGB1P38.
- chr3:81,246,579–82,463,675, 11 genes, copy number 6: AC099542.1, AC107302.2, AC107302.1, GBE1, RNU2-28P, SETP6, AC017015.1, AC017015.2, AC129807.1, LINC02008, RPL7AP23.
- chr3:83,937,045–90,261,708, 47 genes, copy number 6: SRRM1P2, LINC00971, AC117482.1, LINC02025, CADM2, MIR5688, CADM2-AS2, CADM2-AS1, THAP12P2, AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6, AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P, HSPE1P19.
- chr5:34,651,457–45,895,970, 175 genes, copy number 5 (broad region; genes not listed).
- chr6:30,102,897–37,571,460, 410 genes, copy number 5–6 (broad region; genes not listed).
- chr6:56,056,590–56,954,649, 6 genes, copy number 5 (within-gene range 3–5): COL21A1, DHFRP6, AL031779.1, RCC2P7, DST, DST-AS1.
- chr8:64,091–1,708,476, 29 genes, copy number 5: AC144568.1, AC144568.2, AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP, ERICH1, AC100797.1, DLGAP2, AC100797.4, AC026950.2, AC129915.3, AC110288.1, AF067845.2, AF067845.1, DLGAP2-AS1.
- chr10:84,139,509–84,259,960, 6 genes, copy number 6 (within-gene range 2–6): GHITM, C10orf99, CDHR1, LRIT2, RGR, LRIT1.
- chr10:84,328,586–84,561,263, 5 genes, copy number 6: CCSER2, RPL12P29, TNPO1P1, CACYBPP1, RPS3AP5.
- chr12:12,310–2,697,950, 58 genes, copy number 5–10 (within-gene range 3–10): DDX11L8, WASH8P, FAM138D, IQSEC3, AC026369.3, AC026369.1, AC026369.2, AC007406.3, SLC6A12, AC007406.1, SLC6A12-AS1, SLC6A13, AC007406.2, AC007406.4, KDM5A, CCDC77, B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1, RAD52, AC004803.1, ERC1, HTR1DP1, AC004672.1, AC004672.2, LINC00942, WNT5B, FBXL14, MIR3649, ADIPOR2, AC005183.1, AC005343.4, RPS4XP14, CACNA2D4, AC005343.7, LRTM2, AC005342.2, LINC00940, DCP1B, CACNA1C, AC005342.1, CACNA1C-IT1, CACNA1C-IT2, AC005344.1, CACNA1C-AS4, CACNA1C-IT3, AC005293.1, AC005414.1, CACNA1C-AS3, AC007618.1, CACNA1C-AS2.
- chr12:37,575,587–37,576,384, 1 gene, copy number 5: ZNF970P.
- chr12:39,626,167–44,499,158, 63 genes, copy number 8–9 (broad region; genes not listed).
- chr12:45,050,901–45,103,107, 1 gene, copy number 7 (within-gene range 4–7): AC008127.1.
- chr12:45,071,769–45,610,620, 9 genes, copy number 7: SSBL3P, RNA5SP361, PLEKHA8P1, AC009248.1, ANO6, AC009248.2, AC063924.1, AC079950.1, U6.
- chr12:45,919,131–46,876,784, 14 genes, copy number 7: SCAF11, AC084878.1, SLC38A1, AC025031.3, SLC38A2, AC025031.2, AC008014.1, AC025031.1, AC025031.4, AC025031.5, AC008035.1, OR7A19P, MARK3P1, SLC38A4.
- chr14:39,432,599–41,556,055, 5 genes, copy number 5: AL049828.1, LINC02315, AL391516.1, AL356596.1, AL121821.3.
- chr14:42,989,201–46,651,781, 40 genes, copy number 6: AL163153.1, TUBBP3, HNRNPUP1, KRT8P2, AL358913.1, ARHGAP16P, LINC02307, EIF4BP1, AL109766.1, YWHAZP1, AL161752.1, LINC02277, FSCB, AL356022.1, LINC02302, DOCK11P1, AL049870.2, AL049870.1, RRAGAP1, C14orf28, AL049870.3, KLHL28, TOGARAM1, AL121809.2, AL121809.1, PRPF39, SNORD58, SNORD127, FKBP3, FANCM, MIS18BP1, RNU6-552P, DNAJC19P9, AL162632.3, AL162632.1, AL162632.2, AL139354.1, LINC02303, LINC00871, RPL10L.
- chr14:47,760,995–48,491,767, 9 genes, copy number 5–6: MIR548Y, LINC00648, AL121576.1, AL359212.1, AL358335.3, RNU6-297P, AL358335.2, AL358335.1, RPL18P1.
- chr14:49,552,633–50,231,578, 38 genes, copy number 6: RNA5SP384, RPS29, RPL32P29, RN7SL1, Y_RNA, LRR1, RHOQP1, AL139099.3, RPL36AL, MGAT2, AL139099.1, DNAAF2, AL139099.2, POLE2, STK16P1, AL591767.2, RNU6ATAC30P, KLHDC1, AL591767.1, KLHDC2, NEMF, Y_RNA, RNU6-539P, RN7SL3, AL627171.2, RN7SL2, AL627171.1, ARF6, RNU6-189P, Metazoa_SRP, LINC01588, MIR6076, PDLIM1P1, AL117692.1, RN7SKP193, Y_RNA, VCPKMT, SOS2.
- chr14:66,212,810–68,730,218, 44 genes, copy number 6 (within-gene range 2–6): AL359232.1, AL157997.1, CCDC196, GPHN, AL133241.1, AL049835.1, FAM71D, SF3B4P1, MPP5, AL135978.1, ATP6V1D, Y_RNA, EIF2S1, PLEK2, MIR5694, TMEM229B, PLEKHH1, PIGH, AL132640.1, AL132640.2, AL132640.3, Y_RNA, ARG2, AL049779.4, VTI1B, COX7A2P1, RNA5SP386, AL049779.1, RDH11, RDH12, RN7SL369P, RPL21P9, ZFYVE26, AL049779.3, RN7SL213P, AL049779.2, RAD51B, AL133370.2, AL133370.1, RN7SL706P, RN7SL108P, AL122013.1, PPIAP6, AL121820.3.
- chr14:68,693,656–68,695,734, 1 gene, copy number 6: AL133313.1.
- chr14:70,044,215–72,566,530, 50 genes, copy number 5 (within-gene range 2–5): SLC8A3, AL160191.1, AL160191.3, AL160191.2, ADAM21P1, AL356804.1, COX16, SYNJ2BP-COX16, RNU2-51P, SYNJ2BP, AL357153.2, ADAM21, ADAM20P1, RNU6-659P, ADAM20, AL357153.4, MED6, AL357153.3, KRT18P7, AL357153.1, RN7SL77P, TTC9, LINC01269, MAP3K9, AC004816.1, AC004816.2, AC004825.1, AC004825.2, PCNX1, AC004825.3, AC005230.1, GTF3AP2, PTTG4P, AC004817.3, AC004817.5, AC004817.2, AC004817.1, AC004817.4, AC005476.2, SIPA1L1, AC005476.1, SNORD56B, RN7SL683P, AC004974.1, AC004900.1, AC005993.1, RGS6, Y_RNA, AC004828.2, MIR7843.
- chr19:186,373–549,924, 18 genes, copy number 6–9: SEPTIN14P19, CICP19, LINC01002, RNU6-1076P, PLPP2, MIER2, AC016588.1, THEG, AC010641.1, C2CD4C, SHC2, RNA5SP462, ODF3L2, MADCAM1, AC005775.1, TPGS1, CDC34, GZMM.
- chr19:30,946,582–35,169,881, 123 genes, copy number 5 (broad region; genes not listed).
- chr19:36,054,881–37,614,179, 67 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr19:48,993,562–49,108,605, 24 genes, copy number 5: RUVBL2, MIR6798, LHB, AC008687.4, CGB3, AC008687.1, NTF6A, NTF6G, CGB2, CGB1, NTF6B, AC008687.5, CGB5, CGB8, AC008687.6, CGB7, AC008687.8, AC008687.7, AC008687.2, NTF4, AC008687.3, KCNA7, RN7SL708P, SNRNP70.

Autosomal genes at a single copy (total copy number 1): 1,659. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
